Somatic mutation profile of tumor specimen TCGA-L5-A43H-01A (aliquot TCGA-L5-A43H-01A-11D-A247-09) from TCGA case TCGA-L5-A43H, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: GX; Age at diagnosis: 75.5 years (27,592 days).
Specimen TCGA-L5-A43H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6692411-fb87-4a74-a2d8-aa6c798e8d3b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A43H-11A (Solid Tissue Normal), aliquot TCGA-L5-A43H-11A-11D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e25f6f9-27f9-424c-978b-f13b7fc0e1a3

The open-access MAF lists 86 somatic variants for this specimen: 69 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 55, Silent 17, Nonsense Mutation 8, Frame Shift Ins 4, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKMY2 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | catalogued as rs768646683; called by muse, mutect2, varscan2
- ARHGEF2 | c.1958G>A p.R653Q (on ENST00000361247 / NM_001162383.2; = p.R625Q on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV58113418; called by muse, mutect2, varscan2
- ARMH3 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as rs1301593069, COSV64233381; called by muse, mutect2, varscan2
- ATP10D | c.354C>G p.F118L | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV56707776; called by muse, mutect2, varscan2
- CHD1 | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV52343900; called by muse, mutect2
- CLK4 | c.747C>A p.F249L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as COSV60321114; called by muse, mutect2
- CREBBP | c.4627G>C p.D1543H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM065107, CM1414259, COSV52118192, COSV52122852, COSV52129653; called by muse, mutect2, varscan2
- CSMD1 | c.5885G>T p.R1962L (on ENST00000520002; = p.R1961L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59363678; called by muse, mutect2
- DLG1 | c.1018C>G p.Q340E | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.333); catalogued as rs1443802262, COSV58392696; called by muse, mutect2, varscan2
- ESPL1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs761300540, COSV99229849; called by muse, mutect2
- INPP4A | c.2278G>A p.V760I (on ENST00000074304 / NM_001134224.1; = p.V721I on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs984538193; called by muse, mutect2
- IQCE | c.1865+2T>C p.X622_splice | Splice Site (SNP) | VAF 14/106 reads (13%) | catalogued as COSV58080489; called by muse, mutect2, varscan2
- IRGQ | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV60670710; called by muse, mutect2, varscan2
- KIDINS220 | c.506A>G p.Y169C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs780568354; called by muse, mutect2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2
- LAPTM4B | c.794G>A p.S265N (on ENST00000445593; = p.S174N on NM_018407.6) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.828); catalogued as COSV101503490; called by muse, mutect2, varscan2
- LCA5 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100878351; called by muse, mutect2, varscan2
- MAN2C1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.297); catalogued as rs1355056026; called by muse, mutect2, varscan2
- MED12L | c.4880T>C p.L1627S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56380711; called by muse, mutect2
- NAA30 | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as rs1186570124; called by muse, mutect2, varscan2
- PRAG1 | c.3039C>A p.C1013* | Nonsense Mutation (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100421846; called by muse, mutect2, varscan2
- PRLR | c.540G>A p.W180* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs776871201; called by muse, varscan2
- PROKR2 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.317); catalogued as rs576243101, COSV54085395; called by muse, mutect2, varscan2
- RADIL | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs772766287, COSV68199648; called by muse, mutect2, varscan2
- SDAD1 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1480331993; called by muse, mutect2, varscan2
- SIGLEC10 | c.1498G>A p.G500R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs554914804, COSV59483043, COSV59488057; called by muse, mutect2, varscan2
- SPATA31A1 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1351573408; called by muse, mutect2
- SRGAP1 | c.1782G>T p.K594N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.488); catalogued as COSV100754216; called by muse, mutect2, varscan2
- SUPT5H | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.023); catalogued as COSV63238906; called by muse, mutect2, varscan2
- TFAP2A | c.886G>T p.E296* (on ENST00000482890; = p.E288* on NM_001032280.3) | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100117152; called by muse, mutect2, varscan2
- TRARG1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.881); catalogued as rs751457450, COSV61562965; called by muse, mutect2, varscan2
- USP17L2 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1173452461; called by muse, mutect2
- ZNF638 | c.4885G>A p.E1629K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as rs759199913; called by muse, varscan2
- AAR2 | c.541T>C p.C181R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.035); called by muse, mutect2
- ARHGAP5 | c.653A>G p.N218S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ARRB1 | c.141T>A p.Y47* | Nonsense Mutation (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- AWAT2 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- CARF | c.1936G>T p.D646Y | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- CNTN1 | c.514T>C p.W172R | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EIF5B | c.2527C>G p.Q843E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- FAM167B | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.388); called by muse, mutect2
- FZD1 | c.1264dup p.I422Nfs*61 | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- FZD7 | c.1322T>A p.L441Q | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GALNT2 | c.1477A>T p.M493L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- KANSL1L | c.2057_2073del p.N686Mfs*2 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel*, varscan2*
- KDM1B | c.2232_2233dup p.Q745Rfs*28 (on ENST00000449850; = p.Q512Rfs*28 on NM_153042.4) | Frame Shift Ins (INS) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- KIF2A | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2
- KLRK1 | c.482C>A p.P161Q | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LYPD6 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MEF2D | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NDFIP2 | c.785A>G p.Y262C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH3 | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2
- OTUD6B | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDCD11 | c.5422C>A p.H1808N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- PIGR | c.1200C>A p.D400E | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PSMC4 | c.521A>T p.K174M | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RABL6 | c.1710_1711insT p.D571* | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- SDK2 | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA3A | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SENP2 | c.1735A>T p.M579L | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- SNX13 | c.2848C>G p.Q950E | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.014); called by muse, mutect2
- THADA | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP53 | c.403dup p.C135Lfs*14 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | called by mutect2, pindel, varscan2
- ZNF185 | c.1096G>T p.D366Y | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF229 | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ZNF250 | c.689G>A p.S230N | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF606 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2
- ZNF766 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
- ZNF831 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ARFGAP3 | c.630A>T p.V210= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- CCDC14 | c.1932T>C p.P644= (on ENST00000488653; = p.P596= on NM_022757.5) | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- CD68 | c.31C>T p.L11= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- DCLRE1C | c.57C>T p.F19= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as rs1457686297; called by muse, mutect2
- FBXL20 | c.672G>A p.V224= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- FCGR2B | c.237C>T p.S79= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs1199524085, COSV52681258; called by muse, mutect2, varscan2
- GOLPH3 | c.346T>C p.L116= | Silent (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2
- GPI | c.1506C>T p.G502= | Silent (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- ITFG1 | c.1053A>G p.L351= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs370897829; called by muse, mutect2, varscan2
- MEF2C | c.675G>A p.L225= | Silent (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- OR10Z1 | c.843G>A p.V281= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2193G>A p.A731= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs536478075, COSV65341617, COSV65346997; called by muse, mutect2, varscan2
- PDE3A | c.3114C>T p.D1038= | Silent (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- SP110 | c.1065T>C p.T355= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs1333996506; called by muse, mutect2, varscan2
- SRGAP1 | c.2910G>A p.L970= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2
- TCERG1 | c.198C>G p.P66= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- TRPM6 | c.3771C>T p.I1257= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1475071980; called by muse, mutect2, varscan2
